Gene-level copy-number profile of tumor specimen C3N-00150-04 from CPTAC case C3N-00150, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G3; Age at diagnosis: 55.5 years (20,286 days).
Specimen C3N-00150-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 1ce52530-4ed3-4cbc-ad36-9774e0dfe96f.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-00150-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,223 have no estimate.
https://portal.gdc.cancer.gov/files/2495c110-3ccb-4b0a-8aa0-c242373b7ded

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 2,902; copy number 2: 55,050; copy number 3: 295; copy number 4: 153.

Homozygous deletions (total copy number 0; autosomes only): 2,902 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:152,284,350–152,284,460, 1 gene: Y_RNA.
- chr2:172,674,212–173,052,893, 5 genes: AC018712.1, RAPGEF4-AS1, AC018712.2, RAPGEF4, ALDH7A1P2.
- chr2:174,395,730–242,175,634, 1,198 genes (broad region; genes not listed).
- chr3:11,745–119,677,454, 1,690 genes (broad region; genes not listed).
- chr4:51,918,772–51,919,381, 1 gene: AC027271.1.
- chr5:1,353,896–1,523,962, 6 genes: LINC01511, MTCO2P32, AC026748.3, SLC6A3, LPCAT1, MIR6075.
- chr22:21,268,161–21,268,903, 1 gene (within-gene range 0–2): E2F6P3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
